Somatic mutation profile of tumor specimen TCGA-A6-6648-01A (aliquot TCGA-A6-6648-01A-11D-1771-10) from TCGA case TCGA-A6-6648, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Descending colon; AJCC pathologic stage: Stage IVA; Age at diagnosis: 56.5 years (20,641 days).
Specimen TCGA-A6-6648-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 263119a3-bda4-4f0e-9892-45bed0345ce4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-6648-10A (Blood Derived Normal), aliquot TCGA-A6-6648-10A-01D-1771-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df4bd1d4-36c1-4819-8e7d-3a684cb70824

The open-access MAF lists 98 somatic variants for this specimen: 79 protein-altering or splice-affecting, 19 silent.
By variant classification: Missense Mutation 64, Silent 19, Nonsense Mutation 6, Frame Shift Del 4, Splice Site 2, In Frame Del 1, Translation Start Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACP6 | c.1265T>C p.M422T | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs781853603, COSV65078032; called by muse, mutect2, varscan2
- ADAMTS6 | c.3185C>T p.P1062L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58685376; called by muse, mutect2, varscan2
- ADCY8 | c.2242C>A p.L748M | Missense Mutation (SNP) | VAF 75/155 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.73); catalogued as COSV53929744; called by muse, mutect2, varscan2
- AGBL5 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs955009057, COSV59936213; called by mutect2, varscan2
- AKAP17A | c.898C>T p.R300* | Nonsense Mutation (SNP) | VAF 42/179 reads (23%) | catalogued as rs762373160, COSV58312329; called by muse, mutect2, varscan2
- ANKLE1 | c.1684C>T p.R562W (on ENST00000394458; = p.R508W on NM_152363.6) | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as rs146466494; called by muse, mutect2, varscan2
- APC | c.3930del p.I1311Lfs*10 | Frame Shift Del (DEL) | VAF 33/85 reads (39%) | catalogued as CD106451, COSV57326113, COSV57375940; called by mutect2, pindel, varscan2
- ARFGEF2 | c.3247G>A p.D1083N | Missense Mutation (SNP) | VAF 80/579 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.339); catalogued as COSV64215461; called by muse, mutect2, varscan2
- ATAT1 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52542775; called by muse, mutect2, varscan2
- ATR | c.4629_4631del p.E1543del | In Frame Del (DEL) | VAF 40/246 reads (16%) | catalogued as rs755543843; called by pindel, varscan2
- BFSP2 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs200369728; called by muse, mutect2, varscan2
- C1orf50 | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs762133303, COSV65308390, COSV65308504; called by muse, mutect2, varscan2
- CACHD1 | c.2711T>C p.F904S | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV51560483; called by muse, mutect2, varscan2
- CBFA2T2 | c.1687G>A p.G563S | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.033); catalogued as COSV60802234; called by muse, mutect2
- CCNB3 | c.2117C>A p.S706Y | Missense Mutation (SNP) | VAF 69/197 reads (35%) | SIFT tolerated (1); PolyPhen possibly damaging (0.817); catalogued as COSV52080346; called by muse, mutect2, varscan2
- CDK5R1 | c.329C>A p.P110Q | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.53); catalogued as COSV55577128, COSV55581509; called by muse, mutect2, varscan2
- COL11A1 | c.3946G>C p.D1316H | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV62185037, COSV62199244; called by muse, mutect2, varscan2
- CUL7 | c.4919G>A p.R1640Q | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs773657593, COSV99539434; called by muse, mutect2, varscan2
- CYP1A2 | c.1463A>T p.K488I | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.562); catalogued as COSV59661193; called by muse, mutect2, varscan2
- DNAH11 | c.8875G>A p.G2959S | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100181471; called by muse, varscan2
- DUSP4 | c.662G>T p.G221V | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53547978; called by muse, mutect2, varscan2
- DUSP6 | c.93C>A p.N31K | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.91); PolyPhen benign (0.007); catalogued as COSV54379577; called by muse, mutect2, varscan2
- EIPR1 | c.450A>C p.K150N | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.047); catalogued as COSV101182321; called by muse, mutect2, varscan2
- EVL | c.1084T>C p.S362P (on ENST00000402714 / NM_001330221.2; = p.S364P on NM_016337.3) | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.177); catalogued as COSV101233151; called by muse, mutect2, varscan2
- FIBIN | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.832); catalogued as COSV59413640; called by muse, mutect2, varscan2
- GABRA5 | c.1289G>A p.R430Q | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1171210102, COSV59477866; called by muse, mutect2, varscan2
- GP6 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.359); catalogued as rs759426349, COSV100117818; called by muse, mutect2, varscan2
- HDAC7 | c.652G>A p.G218S (on ENST00000427332; = p.G257S on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.033); catalogued as rs1414870213, COSV50410170; called by muse, mutect2, varscan2
- HDAC9 | c.1064C>T p.T355M | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.27); catalogued as rs367766754; called by muse, mutect2, varscan2
- HERC6 | c.955A>G p.T319A | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV52035147; called by muse, mutect2, varscan2
- HIVEP2 | c.1571A>C p.Q524P | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV99177129; called by muse, mutect2, varscan2
- JAK3 | c.1211G>A p.S404N | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71687978; called by muse, mutect2, varscan2
- JAM3 | c.296C>A p.S99Y | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100138540; called by muse, mutect2, varscan2
- KCTD5 | c.155G>A p.G52D | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100069773; called by muse, varscan2
- KIDINS220 | c.5258A>T p.H1753L | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV99876633; called by muse, mutect2, varscan2
- LAMA5 | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 75/113 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs201183803; called by muse, mutect2, varscan2
- LRRK2 | c.5077C>T p.R1693* | Nonsense Mutation (SNP) | VAF 11/97 reads (11%) | catalogued as rs768668969, COSV54154140; called by muse, mutect2, varscan2
- MAP3K14 | c.2576A>G p.N859S | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.637); catalogued as rs371527687; called by muse, mutect2, varscan2
- MAP3K5 | c.3428G>A p.R1143Q | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV62887201; called by muse, mutect2, varscan2
- MAPK6 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV55931870; called by muse, mutect2, varscan2
- MFGE8 | c.983C>T p.A328V | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs1168321086, COSV51558010; called by muse, mutect2, varscan2
- MMP19 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs567533354, COSV59453397; called by muse, mutect2, varscan2
- MUC16 | c.30511A>G p.K10171E | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV101202253; called by muse, mutect2
- MUC4 | c.13468G>A p.G4490S (on ENST00000463781 / NM_018406.7; = p.G254S on NM_004532.6) | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.691); catalogued as rs761654769, COSV57804750; called by muse, mutect2, varscan2
- MYCT1 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 70/167 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs17852097, COSV65891766; called by muse, mutect2, varscan2
- MYH6 | c.1328G>A p.R443H | Missense Mutation (SNP) | VAF 54/149 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs202096001; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO1G | c.2653C>T p.R885W | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1486210938, COSV51857288; called by muse, mutect2, varscan2
- OR1L3 | c.313C>G p.L105V | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.175); catalogued as COSV59170761; called by muse, mutect2, varscan2
- PCDHA5 | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.104); catalogued as COSV65355007; called by muse, mutect2, varscan2
- PCDHB7 | c.2030C>T p.A677V | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.111); catalogued as rs782497916; called by muse, varscan2
- PCDHGC5 | c.2232G>T p.Q744H | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as COSV52770806; called by muse, mutect2, varscan2
- PLPP5 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57667325; called by muse, mutect2, varscan2
- PPARGC1A | c.2389C>T p.R797C | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs34129331; called by muse, mutect2, varscan2
- RP1 | c.4141A>G p.K1381E | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs777613936, COSV55120398, COSV99609255; called by muse, mutect2, varscan2
- RPGRIP1L | c.268A>T p.K90* | Nonsense Mutation (SNP) | VAF 90/149 reads (60%) | catalogued as COSV50918773; called by muse, mutect2, varscan2
- RUSC2 | c.3786G>A p.W1262* | Nonsense Mutation (SNP) | VAF 21/39 reads (54%) | catalogued as COSV63430721; called by muse, mutect2, varscan2
- SATB1 | c.2139G>C p.E713D | Missense Mutation (SNP) | VAF 70/211 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV58673081; called by muse, mutect2, varscan2
- SLC13A3 | c.1219+2T>C p.X407_splice | Splice Site (SNP) | VAF 10/69 reads (14%) | catalogued as rs1489083223, COSV51723664; called by muse, mutect2, varscan2
- SLC17A6 | c.747C>T p.Y249= | Splice Region (SNP) | VAF 85/281 reads (30%) | catalogued as rs753049319, COSV54133640; called by muse, mutect2, varscan2
- SLC2A6 | c.1109A>T p.N370I | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV52471903; called by muse, mutect2, varscan2
- SMARCD3 | c.779C>T p.P260L (on ENST00000262188 / NM_001003801.2; = p.P247L on NM_003078.4) | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50402098; called by muse, mutect2, varscan2
- SMG6 | c.2275C>T p.Q759* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as COSV99558948; called by muse, mutect2, varscan2
- ST6GALNAC2 | c.613A>T p.K205* | Nonsense Mutation (SNP) | VAF 12/72 reads (17%) | catalogued as COSV56572772; called by muse, mutect2, varscan2
- STK4 | c.415T>C p.Y139H | Missense Mutation (SNP) | VAF 51/541 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65672220; called by muse, mutect2
- SUPT16H | c.2180C>T p.A727V | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.059); catalogued as COSV53524273; called by muse, mutect2, varscan2
- SYNE1 | c.2000T>C p.L667P (on ENST00000367255 / NM_182961.4; = p.L674P on NM_033071.3) | Missense Mutation (SNP) | VAF 56/289 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99584130; called by muse, mutect2, varscan2
- TAFA4 | c.356T>C p.L119P | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55146732; called by muse, mutect2, varscan2
- TEC | c.496-1G>A p.X166_splice | Splice Site (SNP) | VAF 97/177 reads (55%) | catalogued as COSV67406604; called by muse, mutect2, varscan2
- TRERF1 | c.3232G>A p.G1078S | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200582061, COSV61678498; called by muse, mutect2
- TRPM1 | c.2449G>A p.G817R | Missense Mutation (SNP) | VAF 39/203 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.068); catalogued as rs766173103, COSV56638205, COSV56643196; called by muse, mutect2, varscan2
- TRPM1 | c.1417C>T p.R473C | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765113979, COSV56632335; called by muse, mutect2, varscan2
- TRPM3 | c.3889G>A p.A1297T (on ENST00000357533 / NM_001366142.2; = p.A1152T on NM_020952.6) | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.018); catalogued as rs549164540, COSV62585202; called by muse, mutect2, varscan2
- UGT2B4 | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.159); catalogued as rs1314997496, COSV59316881; called by muse, mutect2, varscan2
- ZNF367 | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs1401145025, COSV53564963; called by muse, mutect2, varscan2
- ZNF554 | c.1204C>T p.H402Y | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1176529719, COSV57887148; called by muse, mutect2, varscan2
- ZNF84 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1473335327; called by muse, mutect2, varscan2
- LRRC66 | c.1861del p.S621Lfs*6 | Frame Shift Del (DEL) | VAF 42/208 reads (20%) | called by mutect2, pindel, varscan2
- MUC5B | c.14006_14007del p.S4669* | Frame Shift Del (DEL) | VAF 88/308 reads (29%) | called by pindel, varscan2
- SEMA3A | c.2083_2089del p.M695Lfs*81 | Frame Shift Del (DEL) | VAF 39/285 reads (14%) | called by mutect2, pindel, varscan2
- AGMAT | c.957C>T p.V319= | Silent (SNP) | VAF 24/47 reads (51%) | catalogued as rs371989772; called by muse, mutect2, varscan2
- APBA2 | c.441G>A p.P147= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs375569614; called by mutect2, varscan2
- BUB1 | c.1410C>T p.F470= | Silent (SNP) | VAF 32/172 reads (19%) | catalogued as COSV57067503; called by muse, mutect2, varscan2
- CDH13 | c.1506G>A p.T502= | Silent (SNP) | VAF 28/52 reads (54%) | catalogued as rs184869802, COSV51868182; called by muse, mutect2, varscan2
- CRMP1 | c.297C>T p.G99= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV61480875; called by muse, mutect2, varscan2
- DMD | c.8508C>T p.G2836= | Silent (SNP) | VAF 28/112 reads (25%) | catalogued as rs374374549, COSV58956442; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- GDF6 | c.93C>T p.S31= | Silent (SNP) | VAF 34/64 reads (53%) | catalogued as COSV54628059; called by muse, mutect2, varscan2
- JAM3 | c.297C>T p.S99= | Silent (SNP) | VAF 32/116 reads (28%) | catalogued as COSV54457340; called by muse, mutect2, varscan2
- KCNJ1 | c.225C>G p.L75= | Silent (SNP) | VAF 31/87 reads (36%) | catalogued as COSV60662901; called by muse, mutect2, varscan2
- LRP1 | c.5451C>T p.G1817= | Silent (SNP) | VAF 41/98 reads (42%) | catalogued as COSV54527538; called by muse, mutect2, varscan2
- OR5L1 | c.174C>G p.P58= | Silent (SNP) | VAF 51/219 reads (23%) | catalogued as COSV100450019, COSV100450340; called by muse, mutect2, varscan2
- PCDHA9 | c.1353C>T p.N451= | Silent (SNP) | VAF 45/154 reads (29%) | catalogued as rs1554143388, COSV65324575; called by muse, mutect2, varscan2
- PCDHB8 | c.1554G>A p.R518= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as COSV50820665; called by muse, mutect2, varscan2
- PCDHGA10 | c.2238C>T p.G746= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as rs780730425, COSV53926494; called by muse, mutect2, varscan2
- PHF6 | c.537C>T p.T179= (on ENST00000332070 / NM_032458.3; = p.T180= on NM_032335.3) | Silent (SNP) | VAF 44/136 reads (32%) | catalogued as rs776473521, COSV59706988; called by muse, mutect2, varscan2
- PTPRN2 | c.1026C>T p.G342= | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as rs769163767, COSV67060969; called by muse, mutect2, varscan2
- SIN3B | c.2790C>T p.C930= | Silent (SNP) | VAF 25/52 reads (48%) | catalogued as rs1380957676, COSV56136752; called by muse, mutect2, varscan2
- ZFP14 | c.1527G>A p.K509= | Silent (SNP) | VAF 45/144 reads (31%) | catalogued as rs1374455457, COSV99525388; called by muse, mutect2, varscan2
- ZSCAN2 | c.36G>A p.P12= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as rs367963102, COSV59109516; called by muse, mutect2, varscan2
